Somatic mutation profile of tumor specimen MP2PRT-PAUJWN-TMP1-A (aliquot MP2PRT-PAUJWN-TMP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAUJWN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,200 days).
Specimen MP2PRT-PAUJWN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e415bc46-c9e8-4a43-b2ed-1391409fb89d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUJWN-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUJWN-NM1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b50343f-26d9-42ad-ac63-adb9df6c35dc

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 10, Silent 3, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD52 | c.2862C>G p.I954M | Missense Mutation (SNP) | VAF 15/475 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV57284184; called by muse, mutect2
- ARHGEF17 | c.4684C>T p.R1562C | Missense Mutation (SNP) | VAF 134/448 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs770686925; called by muse, mutect2, varscan2
- CCDC136 | c.2020C>T p.R674* | Nonsense Mutation (SNP) | VAF 58/245 reads (24%) | catalogued as COSV52804518; called by muse, varscan2
- CNN1 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 111/451 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs368198606; called by muse, mutect2, varscan2
- COL14A1 | c.3724G>T p.D1242Y | Missense Mutation (SNP) | VAF 58/225 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.201); catalogued as COSV52863853, COSV52869803; called by mutect2, varscan2
- DNAJC6 | c.1706C>T p.A569V | Missense Mutation (SNP) | VAF 94/333 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.051); catalogued as rs761922985; called by muse, mutect2, varscan2
- RTL1 | c.2824G>A p.E942K | Missense Mutation (SNP) | VAF 102/379 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.267); catalogued as rs781425496, COSV66016588; called by muse, mutect2, varscan2
- RWDD2A | c.772G>C p.D258H | Missense Mutation (SNP) | VAF 45/231 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99392556; called by muse, mutect2, varscan2
- SH3TC2 | c.1973G>A p.R658H | Missense Mutation (SNP) | VAF 201/539 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.36); catalogued as rs138040787; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBA2 | c.1246-1G>A p.X416_splice | Splice Site (SNP) | VAF 60/207 reads (29%) | catalogued as COSV55827325, COSV55829013; called by muse, mutect2, varscan2
- GABRA6 | c.298A>T p.I100F | Missense Mutation (SNP) | VAF 100/397 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ZNF717 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 42/356 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2
- FSTL5 | c.513C>T p.D171= | Silent (SNP) | VAF 71/251 reads (28%) | catalogued as rs201353835; called by muse, mutect2, varscan2
- TRIM37 | c.1248T>C p.H416= | Silent (SNP) | VAF 85/279 reads (30%) | catalogued as rs1278909585; called by muse, varscan2
- ZNRF3 | c.951G>A p.R317= (on ENST00000544604 / NM_001206998.2; = p.R217= on NM_032173.3) | Silent (SNP) | VAF 17/480 reads (4%) | called by muse, mutect2
